Gene-level copy-number profile of tumor specimen BLGSP-71-27-00430-01A from CGCI case BLGSP-71-27-00430, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 47.6 years (17,380 days).
Specimen BLGSP-71-27-00430-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dc10b5f5-859f-4bfe-a8a6-c8752aa1a51e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-27-00430-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/3594ef4c-4e00-4c3c-9f44-f0252e4ba59d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 212; copy number 1: 7,663; copy number 2: 49,664; copy number 3: 1,020; copy number 4: 236; copy number 5: 110; copy number 6: 2; copy number 7: 4; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): 212 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,036,958–130,145,134, 8 genes (within-gene range 0–2): KLF2P1, CYP4F27P, POTEF, AC018865.1, POTEF-AS1, RNU6-1049P, MED15P9, CCDC74B.
- chr4:49,203,171–49,246,915, 7 genes: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22.
- chr7:38,239,580–38,340,998, 15 genes (within-gene range 0–2): TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV7, TRGV6.
- chr14:22,105,343–22,552,156, 94 genes (within-gene range 0–7) (broad region; genes not listed).
- chr15:21,307,749–21,307,855, 1 gene (within-gene range 0–5): RNU6-1235P.
- chr15:21,951,242–21,951,323, 1 gene: MIR5701-3.
- chr15:22,056,709–22,057,638, 1 gene (within-gene range 0–1): OR4H6P.
- chr17:63,471,604–63,548,977, 5 genes: PPIAP55, ACE, AC113554.1, ACE3P, KCNH6.
- chr19:53,599,628–54,081,365, 80 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 117 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,485,030–160,754,821, 8 genes, copy number 5: SLAMF6, AL138930.1, CD84, SLAMF1, SETP9, AL121985.1, CD48, SLAMF7.
- chr2:135,905,881–136,233,245, 6 genes, copy number 5: DARS1, DARS-AS1, AC068492.1, CXCR4, HNRNPKP2, AC112255.1.
- chr2:196,133,583–196,176,503, 2 genes, copy number 6: STK17B, AC114760.2.
- chr6:25,962,802–26,123,926, 19 genes, copy number 5: TRIM38, U91328.2, U91328.1, U91328.3, H3P26, H1-1, H3C1, H4C1, H4C2, H3C2, H2AC4, H2BC3, H2AC5P, H3C3, H1-2, HFE, H4C3, H1-6, H2BC4.
- chr6:32,517,353–33,089,696, 32 genes, copy number 5: HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1, HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1, MTCO3P1, AL662789.1, HLA-DQB3, HLA-DQA2, MIR3135B, HLA-DQB2, HLA-DOB, AL669918.1, TAP2, PSMB8, PSMB8-AS1, PSMB9, TAP1, PPP1R2P1, HLA-Z, HLA-DMB, AL645941.2, HLA-DMA, BRD2, AL645941.1, AL645941.3, HLA-DOA, HLA-DPA1, HLA-DPB1, RPL32P1.
- chr6:158,972,871–159,170,007, 7 genes, copy number 5 (within-gene range 2–5): RSPH3, AL035530.2, TAGAP, AL035530.1, AL356417.3, AL356417.1, AL356417.2.
- chr14:22,556,311–22,589,224, 3 genes, copy number 7: LINC02332, AC243965.1, DAD1.
- chr15:21,293,653–21,325,241, 2 genes, copy number 5–7 (within-gene range 0–7): AC068446.1, AC068446.2.
- chr15:21,328,380–21,877,735, 33 genes, copy number 5: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P.
- chr15:21,980,277–21,981,245, 1 gene, copy number 21: OR11J6P.
- chr15:92,819,540–93,027,996, 4 genes, copy number 5: CHASERR, AC013394.1, CHD2, MIR3175.

Autosomal genes at a single copy (total copy number 1): 4,827. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
